Somatic mutation profile of tumor specimen TCGA-58-8391-01A (aliquot TCGA-58-8391-01A-11D-2323-08) from TCGA case TCGA-58-8391, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 57.8 years (21,102 days).
Specimen TCGA-58-8391-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1c719d86-a127-4b63-a64a-64cc9a7cb12f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-58-8391-10A (Blood Derived Normal), aliquot TCGA-58-8391-10A-01D-2323-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/eeef8b04-b4ab-46e7-bd5c-d37fcc3261f9

The open-access MAF lists 373 somatic variants for this specimen: 285 protein-altering or splice-affecting, 76 silent, 12 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 248, Silent 76, Nonsense Mutation 15, Frame Shift Del 10, Intron 5, Splice Site 5, Frame Shift Ins 3, RNA 3, Splice Region 2, 5'Flank 2, 3'UTR 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.734G>T p.G245V | Missense Mutation (SNP) | VAF 61/89 reads (69%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121912656, CM010464, CM900209, COSV52666323, COSV52667838, COSV52745465; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABHD17B | c.109C>A p.L37M | Missense Mutation (SNP) | VAF 73/145 reads (50%) | SIFT deleterious (0.05); PolyPhen benign (0.248); catalogued as COSV100330315; called by muse, mutect2, varscan2
- ACVR1 | c.656A>G p.Y219C | Missense Mutation (SNP) | VAF 50/154 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1198591575, COSV99718207; called by muse, mutect2, varscan2
- ADAM7 | c.1712G>T p.G571V | Missense Mutation (SNP) | VAF 17/83 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99445323; called by muse, mutect2, varscan2
- ADAMTS2 | c.552G>A p.M184I | Missense Mutation (SNP) | VAF 32/101 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.136); catalogued as COSV99206348; called by muse, mutect2, varscan2
- ADAMTS20 | c.2572G>T p.G858C | Missense Mutation (SNP) | VAF 54/123 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.749); catalogued as COSV101166429; called by muse, mutect2, varscan2
- ADAMTS3 | c.1218G>A p.M406I | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.705); catalogued as COSV99710364, COSV99712378; called by muse, mutect2, varscan2
- ADAP1 | c.898G>A p.G300S | Missense Mutation (SNP) | VAF 95/222 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99763471; called by muse, mutect2, varscan2
- AGTPBP1 | c.1054C>A p.P352T (on ENST00000357081 / NM_001330701.2; = p.P312T on NM_015239.2) | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.811); catalogued as COSV100430422; called by muse, mutect2, varscan2
- AK8 | c.480C>G p.H160Q | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100050632; called by muse, mutect2, varscan2
- ALS2 | c.2785G>T p.G929W | Missense Mutation (SNP) | VAF 126/171 reads (74%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99970186; called by muse, mutect2, varscan2
- AMPH | c.2030G>T p.R677I | Missense Mutation (SNP) | VAF 62/156 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV100340757; called by muse, varscan2
- AMY1A | c.1028T>A p.M343K | Missense Mutation (SNP) | VAF 8/12 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100915803; called by mutect2, varscan2
- ANP32E | c.565G>C p.E189Q | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.043); catalogued as COSV100029798; called by muse, mutect2, varscan2
- ANTXR1 | c.754G>T p.V252L | Missense Mutation (SNP) | VAF 133/410 reads (32%) | SIFT tolerated (0.32); PolyPhen benign (0.376); catalogued as COSV100363264; called by muse, mutect2, varscan2
- AP1G1 | c.848A>C p.N283T | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.844); catalogued as COSV100251135, COSV55493118; called by muse, mutect2, varscan2
- APBA2 | c.1201G>A p.V401I | Missense Mutation (SNP) | VAF 20/69 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.642); catalogued as COSV67104623; called by muse, mutect2, varscan2
- APC | c.6539A>G p.K2180R | Missense Mutation (SNP) | VAF 49/79 reads (62%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.985); catalogued as rs762955111, COSV99970896; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- APCS | c.660G>T p.L220F | Missense Mutation (SNP) | VAF 28/128 reads (22%) | SIFT tolerated (0.42); PolyPhen benign (0.096); catalogued as COSV99661561; called by muse, mutect2, varscan2
- API5 | c.69+1G>T p.X23_splice | Splice Site (SNP) | VAF 4/29 reads (14%) | catalogued as COSV101124622, COSV66632970; called by muse, mutect2, varscan2
- API5 | c.1145G>T p.R382L | Missense Mutation (SNP) | VAF 30/71 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV101124623, COSV66632411, COSV66633371; called by muse, mutect2, varscan2
- APOL3 | c.479A>G p.K160R (on ENST00000349314 / NM_145640.2; = p.K89R on NM_014349.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 24/108 reads (22%) | SIFT tolerated (0.15); PolyPhen benign (0.033); catalogued as rs201358512, COSV100652186; called by muse, mutect2, varscan2
- ARFIP1 | c.433G>T p.E145* (on ENST00000353617 / NM_001287432.1; = p.E113* on NM_014447.3 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 48/87 reads (55%) | catalogued as COSV100617350; called by muse, mutect2, varscan2
- ATP6V0A4 | c.722+2T>A p.X241_splice | Splice Site (SNP) | VAF 65/297 reads (22%) | catalogued as COSV100023805; called by muse, mutect2, varscan2
- B3GAT1 | c.233C>T p.P78L | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.101); catalogued as COSV100438262; called by muse, mutect2, varscan2
- BDP1 | c.5386A>T p.S1796C | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100703664; called by muse, mutect2, varscan2
- BEND5 | c.850G>A p.A284T | Missense Mutation (SNP) | VAF 28/146 reads (19%) | SIFT tolerated (0.19); PolyPhen benign (0.001); catalogued as rs748499198, COSV65717838; called by muse, mutect2, varscan2
- BIRC6 | c.12896C>G p.S4299C | Missense Mutation (SNP) | VAF 18/64 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101429132, COSV101429230; called by muse, mutect2, varscan2
- BMP8A | c.698C>T p.A233V | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT tolerated (0.12); PolyPhen benign (0.134); catalogued as COSV100090301; called by mutect2, varscan2
- BOD1L1 | c.7675T>A p.S2559T | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.013); catalogued as COSV99240591; called by muse, mutect2, varscan2
- BOD1L1 | c.6744A>T p.E2248D | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.132); catalogued as COSV99240593; called by muse, mutect2, varscan2
- BRINP1 | c.767G>A p.G256E | Missense Mutation (SNP) | VAF 35/128 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV99777198, COSV99777313; called by muse, mutect2, varscan2
- BRINP3 | c.1859C>G p.T620R | Missense Mutation (SNP) | VAF 59/396 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100818250, COSV100819605; called by muse, mutect2, varscan2
- C16orf92 | c.225C>A p.D75E | Missense Mutation (SNP) | VAF 24/59 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); catalogued as COSV99662622; called by muse, mutect2, varscan2
- C1S | c.1415C>T p.T472M | Missense Mutation (SNP) | VAF 11/128 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs782089371, COSV100196812; called by muse, mutect2
- C1S | c.1668C>G p.D556E | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV100196814; called by muse, mutect2, varscan2
- C1orf94 | c.1375C>G p.P459A (on ENST00000488417 / NM_001134734.2; = p.P269A on NM_032884.5) | Missense Mutation (SNP) | VAF 23/109 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1227010551, COSV100975283; called by muse, mutect2, varscan2
- CARF | c.897dup p.V300Sfs*3 | Frame Shift Ins (INS) | VAF 164/223 reads (74%) | catalogued as rs751635415; called by mutect2, varscan2
- CATSPERE | c.733G>A p.A245T | Missense Mutation (SNP) | VAF 35/76 reads (46%) | SIFT tolerated (0.38); PolyPhen benign (0.013); catalogued as COSV100835427; called by muse, mutect2, varscan2
- CCDC102A | c.713C>A p.P238H | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.723); catalogued as COSV99265280; called by muse, mutect2, varscan2
- CCP110 | c.1288A>G p.T430A | Missense Mutation (SNP) | VAF 47/149 reads (32%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as rs973873957, COSV101195358; called by muse, mutect2, varscan2
- CD5L | c.553G>C p.V185L | Missense Mutation (SNP) | VAF 80/143 reads (56%) | SIFT tolerated (0.64); PolyPhen benign (0.007); catalogued as COSV100941230; called by muse, mutect2, varscan2
- CETN1 | c.365C>A p.S122* | Nonsense Mutation (SNP) | VAF 80/152 reads (53%) | catalogued as COSV100511432; called by muse, mutect2, varscan2
- CFAP54 | c.4726A>G p.M1576V | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as COSV100733422; called by muse, mutect2, varscan2
- CHD7 | c.4108G>C p.G1370R | Missense Mutation (SNP) | VAF 39/166 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101418556; called by muse, mutect2, varscan2
- CLCN2 | c.2065G>C p.G689R | Missense Mutation (SNP) | VAF 207/455 reads (45%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as rs775575872, COSV99659107; called by muse, mutect2, varscan2
- CLNK | c.789G>A p.M263I | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT tolerated (0.26); PolyPhen benign (0.014); catalogued as COSV57015624, COSV99906049; called by muse, mutect2, varscan2
- CLUL1 | c.688C>T p.P230S | Missense Mutation (SNP) | VAF 109/181 reads (60%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.55); catalogued as COSV100621040; called by muse, mutect2, varscan2
- CNNM3 | c.32T>A p.L11* | Nonsense Mutation (SNP) | VAF 8/22 reads (36%) | catalogued as COSV100562816; called by muse, mutect2
- COL11A1 | c.4811C>A p.A1604D | Missense Mutation (SNP) | VAF 29/113 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.351); catalogued as COSV100618321; called by muse, mutect2, varscan2
- COL15A1 | c.1937G>T p.G646V | Missense Mutation (SNP) | VAF 32/91 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100898074; called by muse, mutect2, varscan2
- COL4A2 | c.2581C>T p.R861C | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.953); catalogued as rs751658527, COSV100847529; called by muse, mutect2, varscan2
- COL6A3 | c.5399G>C p.G1800A | Missense Mutation (SNP) | VAF 175/225 reads (78%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as COSV99802272; called by muse, mutect2, varscan2
- COLQ | c.321+1G>C p.X107_splice | Splice Site (SNP) | VAF 58/100 reads (58%) | catalogued as COSV101082606; called by muse, mutect2, varscan2
- CP | c.2254G>A p.E752K | Missense Mutation (SNP) | VAF 72/291 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV52834452; called by muse, mutect2, varscan2
- CPA4 | c.285G>A p.Q95= | Splice Region (SNP) | VAF 12/64 reads (19%) | catalogued as COSV99745430; called by muse, mutect2, varscan2
- CR1 | c.4493G>T p.C1498F | Missense Mutation (SNP) | VAF 25/92 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100888095; called by muse, mutect2, varscan2
- CRACD | c.496A>T p.K166* | Nonsense Mutation (SNP) | VAF 40/110 reads (36%) | catalogued as COSV99950176; called by muse, mutect2, varscan2
- CSMD1 | c.10118C>T p.T3373I (on ENST00000520002; = p.T3372I on NM_033225.6) | Missense Mutation (SNP) | VAF 19/35 reads (54%) | SIFT deleterious (0.04); PolyPhen benign (0.212); catalogued as rs763379840, COSV100154845; called by muse, mutect2, varscan2
- CSMD1 | c.2647G>T p.G883C (on ENST00000520002; = p.G882C on NM_033225.6) | Missense Mutation (SNP) | VAF 10/18 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100154848, COSV59291731; called by muse, varscan2
- CTTNBP2NL | c.511G>A p.E171K | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as rs761221314, COSV54747504; called by muse, mutect2
- CYP11B2 | c.94C>A p.P32T | Missense Mutation (SNP) | VAF 23/154 reads (15%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.743); catalogued as COSV100011460; called by muse, varscan2
- DCC | c.655A>T p.S219C | Missense Mutation (SNP) | VAF 13/84 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV100503662; called by muse, mutect2, varscan2
- DDX53 | c.995G>T p.G332V | Missense Mutation (SNP) | VAF 47/81 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100029145; called by muse, mutect2, varscan2
- DENND5B | c.3244G>A p.G1082R | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as COSV100172394; called by muse, mutect2
- DGKK | c.1187A>T p.N396I | Missense Mutation (SNP) | VAF 9/12 reads (75%) | SIFT tolerated (0.16); PolyPhen benign (0.025); catalogued as COSV101053262; called by muse, mutect2, varscan2
- DISP3 | c.194G>A p.G65D | Missense Mutation (SNP) | VAF 39/68 reads (57%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.881); catalogued as rs758971872, COSV99610229; called by muse, mutect2, varscan2
- DLGAP2 | c.2908C>T p.R970W | Missense Mutation (SNP) | VAF 22/121 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.827); catalogued as rs755873139, COSV70097859; called by muse, mutect2, varscan2
- DMXL2 | c.7238A>G p.D2413G | Missense Mutation (SNP) | VAF 90/216 reads (42%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.612); catalogued as rs1476216643, COSV99198891; called by muse, mutect2, varscan2
- DNAH2 | c.1900G>C p.D634H | Missense Mutation (SNP) | VAF 26/73 reads (36%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.746); catalogued as COSV99318652; called by muse, mutect2, varscan2
- DNAH5 | c.1513G>C p.E505Q | Missense Mutation (SNP) | VAF 23/96 reads (24%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.739); catalogued as COSV54242131, COSV99448644, COSV99455380; called by muse, mutect2
- DNAI4 | c.2246T>C p.V749A | Missense Mutation (SNP) | VAF 35/155 reads (23%) | SIFT tolerated (0.6); PolyPhen benign (0.086); catalogued as COSV100925514; called by muse, mutect2, varscan2
- DNAJC22 | c.784A>G p.K262E | Missense Mutation (SNP) | VAF 24/88 reads (27%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.459); catalogued as COSV101222626; called by muse, mutect2, varscan2
- DOP1A | c.3866A>C p.E1289A | Missense Mutation (SNP) | VAF 19/45 reads (42%) | SIFT tolerated (0.24); PolyPhen benign (0.104); catalogued as COSV99383121; called by muse, mutect2, varscan2
- DUSP26 | c.149G>A p.R50Q | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT tolerated (0.41); PolyPhen benign (0.024); catalogued as rs150556959, COSV99823408; called by muse, mutect2, varscan2
- EDEM3 | c.908A>G p.Y303C | Missense Mutation (SNP) | VAF 39/66 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1274218919, COSV100545737; called by muse, mutect2, varscan2
- EEF1A2 | c.892G>T p.A298S | Missense Mutation (SNP) | VAF 38/198 reads (19%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0.189); catalogued as COSV99420065; called by muse, mutect2, varscan2
- EPAS1 | c.1448A>G p.N483S | Missense Mutation (SNP) | VAF 46/103 reads (45%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1366088332, COSV55389063; called by muse, mutect2, varscan2
- ERICH3 | c.4099G>T p.E1367* | Nonsense Mutation (SNP) | VAF 90/194 reads (46%) | catalogued as COSV100446075, COSV58602494; called by muse, mutect2, varscan2
- ETNK1 | c.300G>T p.L100F | Missense Mutation (SNP) | VAF 38/155 reads (25%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.99); catalogued as COSV99861042, COSV99861076; called by muse, mutect2, varscan2
- FAM135B | c.708C>A p.H236Q | Missense Mutation (SNP) | VAF 21/104 reads (20%) | SIFT tolerated (0.05); PolyPhen benign (0.01); catalogued as rs192537076, COSV52727002; called by muse, mutect2, varscan2
- FBP1 | c.582C>A p.F194L | Missense Mutation (SNP) | VAF 24/187 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100941372; called by muse, mutect2, varscan2
- FBXO45 | c.313G>A p.A105T | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT tolerated (0.53); PolyPhen benign (0.007); catalogued as rs1304001240, COSV100218164; called by muse, mutect2
- FHL5 | c.79C>A p.P27T | Missense Mutation (SNP) | VAF 47/98 reads (48%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.594); catalogued as COSV100459834, COSV100459890; called by muse, mutect2, varscan2
- FMN2 | c.2938C>G p.P980A | Missense Mutation (SNP) | VAF 12/74 reads (16%) | SIFT tolerated, low confidence (0.09); PolyPhen probably damaging (0.945); catalogued as COSV100146937, COSV100147731; called by muse, mutect2, varscan2
- FMN2 | c.3487C>A p.P1163T | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.971); catalogued as COSV100147732; called by muse, mutect2, varscan2
- FMNL1 | c.614A>G p.K205R | Missense Mutation (SNP) | VAF 34/108 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as COSV100057078; called by muse, mutect2, varscan2
- FOLR3 | c.24G>T p.M8I | Missense Mutation (SNP) | VAF 56/499 reads (11%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as COSV100281902; called by muse, mutect2, varscan2
- FPR2 | c.65A>T p.Y22F | Missense Mutation (SNP) | VAF 42/73 reads (58%) | SIFT tolerated (0.14); PolyPhen benign (0.209); catalogued as COSV100389496; called by muse, mutect2, varscan2
- FTMT | c.231G>T p.E77D | Missense Mutation (SNP) | VAF 42/62 reads (68%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.666); catalogued as COSV100360408; called by muse, mutect2, varscan2
- GABRQ | c.889A>G p.R297G | Missense Mutation (SNP) | VAF 200/334 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100941449; called by muse, mutect2, varscan2
- GABRR1 | c.106A>T p.M36L | Missense Mutation (SNP) | VAF 28/55 reads (51%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0); catalogued as rs1205935723, COSV101034189; called by muse, mutect2
- GALC | c.1807G>C p.G603R | Missense Mutation (SNP) | VAF 36/141 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV99730717; called by muse, mutect2, varscan2
- GDPD1 | c.41G>A p.G14E | Missense Mutation (SNP) | VAF 71/245 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.796); catalogued as COSV99405409; called by muse, mutect2, varscan2
- GJA8 | c.491G>T p.G164V | Missense Mutation (SNP) | VAF 32/214 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99569812; called by muse, mutect2, varscan2
- GLIPR1L1 | c.513C>A p.Y171* | Nonsense Mutation (SNP) | VAF 27/76 reads (36%) | catalogued as COSV100158428; called by muse, mutect2, varscan2
- GNAZ | c.517G>A p.E173K | Missense Mutation (SNP) | VAF 53/121 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.001); catalogued as rs1457866450, COSV99321324; called by muse, mutect2, varscan2
- GON4L | c.6304G>T p.D2102Y | Missense Mutation (SNP) | VAF 31/186 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.656); catalogued as COSV99676118; called by muse, mutect2, varscan2
- GPR17 | c.835T>C p.Y279H | Missense Mutation (SNP) | VAF 20/102 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs750304753, COSV99760817; called by muse, mutect2, varscan2
- GRAMD4 | c.1232C>G p.S411* | Nonsense Mutation (SNP) | VAF 4/12 reads (33%) | catalogued as COSV100730696; called by muse, mutect2, varscan2
- GRIK3 | c.1441T>A p.Y481N | Missense Mutation (SNP) | VAF 56/250 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100902450; called by muse, mutect2, varscan2
- GRM1 | c.727G>T p.A243S | Missense Mutation (SNP) | VAF 22/111 reads (20%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.837); catalogued as COSV99269638; called by muse, mutect2, varscan2
- HCAR2 | c.561G>C p.Q187H | Missense Mutation (SNP) | VAF 46/125 reads (37%) | SIFT tolerated (0.05); PolyPhen benign (0.393); catalogued as COSV100186679; called by muse, varscan2
- HGSNAT | c.1351C>G p.H451D | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as COSV99925566; called by muse, mutect2, varscan2
- HIRA | c.1614-1G>T p.X538_splice | Splice Site (SNP) | VAF 26/42 reads (62%) | catalogued as COSV99601004; called by muse, mutect2, varscan2
- HSF5 | c.1222G>A p.G408S | Missense Mutation (SNP) | VAF 40/87 reads (46%) | SIFT tolerated (0.19); PolyPhen benign (0.168); catalogued as rs1446574307, COSV100090934; called by muse, mutect2, varscan2
- IBTK | c.1427-1G>A p.X476_splice | Splice Site (SNP) | VAF 9/21 reads (43%) | catalogued as COSV100091643; called by muse, mutect2
- IFRD1 | c.1213G>T p.V405L | Missense Mutation (SNP) | VAF 28/80 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV99134478; called by muse, mutect2, varscan2
- IGFALS | c.1604G>A p.G535D | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT tolerated (0.12); PolyPhen benign (0.066); catalogued as rs1408244139, COSV99236734; called by muse, mutect2, varscan2
- IGHV3-43 | c.65A>T p.Q22L | Missense Mutation (SNP) | VAF 42/139 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.271); catalogued as rs1224949847; called by muse, mutect2, varscan2
- INPP5F | c.1300C>G p.L434V | Missense Mutation (SNP) | VAF 31/45 reads (69%) | SIFT tolerated (0.3); PolyPhen benign (0.001); catalogued as COSV100740454; called by muse, mutect2, varscan2
- INSL6 | c.104G>C p.R35T | Missense Mutation (SNP) | VAF 70/92 reads (76%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.863); catalogued as COSV101068460, COSV101068548; called by muse, mutect2, varscan2
- ITPRID1 | c.982C>G p.P328A | Missense Mutation (SNP) | VAF 26/83 reads (31%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.453); catalogued as COSV100087812; called by muse, mutect2, varscan2
- KALRN | c.7642T>G p.C2548G (on ENST00000360013 / NM_001024660.4; = p.C851G on NM_007064.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 35/152 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.087); catalogued as COSV99363195; called by muse, mutect2, varscan2
- KCNAB1 | c.82G>T p.V28L | Missense Mutation (SNP) | VAF 130/242 reads (54%) | SIFT tolerated, low confidence (0.54); PolyPhen benign (0); catalogued as COSV101051528; called by muse, mutect2, varscan2
- KCNJ8 | c.812T>A p.I271N | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99557762; called by muse, mutect2, varscan2
- KDR | c.1126A>T p.T376S | Missense Mutation (SNP) | VAF 25/65 reads (38%) | SIFT tolerated (1); PolyPhen possibly damaging (0.726); catalogued as COSV99818582, COSV99818918; called by muse, mutect2, varscan2
- KIF18B | c.285C>G p.D95E | Missense Mutation (SNP) | VAF 28/85 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0.437); catalogued as COSV100192688; called by muse, mutect2, varscan2
- KIR3DL2 | c.1136G>C p.G379A | Missense Mutation (SNP) | VAF 21/142 reads (15%) | SIFT tolerated (0.66); PolyPhen probably damaging (0.996); catalogued as COSV99552410; called by muse, varscan2
- KIRREL3 | c.1474G>T p.D492Y | Missense Mutation (SNP) | VAF 26/52 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101375244; called by muse, mutect2, varscan2
- KLF1 | c.962C>A p.A321E | Missense Mutation (SNP) | VAF 14/91 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99322542; called by muse, mutect2
- KLK2 | c.220T>C p.W74R | Missense Mutation (SNP) | VAF 16/66 reads (24%) | SIFT tolerated (0.3); PolyPhen benign (0.081); catalogued as COSV100320082; called by muse, mutect2, varscan2
- KRBA2 | c.199G>A p.D67N | Missense Mutation (SNP) | VAF 94/133 reads (71%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.009); catalogued as COSV100497735; called by muse, mutect2, varscan2
- KRT73 | c.385C>A p.R129S | Missense Mutation (SNP) | VAF 56/162 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.519); catalogued as COSV59838883, COSV99988265; called by muse, mutect2, varscan2
- KSR2 | c.566C>G p.P189R | Missense Mutation (SNP) | VAF 36/105 reads (34%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV100351462, COSV60366465, COSV60384960; called by muse, mutect2, varscan2
- LAMA4 | c.1162G>T p.A388S (on ENST00000230538 / NM_001105206.3; = p.A381S on NM_002290.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT tolerated (0.17); PolyPhen benign (0.197); catalogued as COSV100039746; called by muse, mutect2, varscan2
- LHX5 | c.173G>A p.R58K | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.888); catalogued as COSV99922583; called by muse, mutect2, varscan2
- LIFR | c.2107G>C p.G703R | Missense Mutation (SNP) | VAF 33/88 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV54686491, COSV99665753; called by muse, mutect2, varscan2
- LRP1B | c.13620C>G p.I4540M | Missense Mutation (SNP) | VAF 37/160 reads (23%) | SIFT tolerated (0.15); PolyPhen benign (0.102); catalogued as COSV101262146; called by muse, mutect2, varscan2
- LRP1B | c.8592G>C p.Q2864H | Missense Mutation (SNP) | VAF 72/144 reads (50%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.837); catalogued as COSV101262147; called by muse, mutect2, varscan2
- LRRIQ1 | c.5044G>C p.D1682H | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV101280760; called by muse, mutect2, varscan2
- MACO1 | c.306del p.F102Lfs*47 | Frame Shift Del (DEL) | VAF 5/30 reads (17%) | catalogued as rs752439249; called by mutect2, varscan2
- MESP1 | c.461G>T p.R154L | Missense Mutation (SNP) | VAF 17/35 reads (49%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as COSV100262388; called by muse, mutect2, varscan2
- MESP1 | c.74C>T p.P25L | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.003); catalogued as COSV100262390; called by muse, mutect2, varscan2
- MISP | c.391G>T p.A131S | Missense Mutation (SNP) | VAF 21/37 reads (57%) | SIFT tolerated (0.19); PolyPhen benign (0.029); catalogued as rs147697749, COSV99297196; called by muse, mutect2, varscan2
- MMP16 | c.1201G>T p.G401W | Missense Mutation (SNP) | VAF 33/78 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54158951, COSV99690850; called by muse, mutect2, varscan2
- MSR1 | c.835G>C p.G279R | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100027685, COSV100028287; called by muse, mutect2, varscan2
- MUC16 | c.21088A>G p.I7030V | Missense Mutation (SNP) | VAF 61/279 reads (22%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.031); catalogued as rs1248928561, COSV101202118; called by muse, mutect2, varscan2
- MUC16 | c.20630T>G p.I6877R | Missense Mutation (SNP) | VAF 33/151 reads (22%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.006); catalogued as COSV101202119; called by muse, mutect2, varscan2
- MYH13 | c.4942C>T p.R1648C | Missense Mutation (SNP) | VAF 22/29 reads (76%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.954); catalogued as rs375642990; called by muse, mutect2, varscan2
- MYH3 | c.660A>T p.Q220H | Missense Mutation (SNP) | VAF 24/143 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV99879069; called by muse, mutect2, varscan2
- NACA2 | c.50del p.P17Rfs*105 | Frame Shift Del (DEL) | VAF 27/107 reads (25%) | catalogued as COSV71713186; called by mutect2, pindel, varscan2
- NAV3 | c.40G>T p.A14S | Missense Mutation (SNP) | VAF 73/202 reads (36%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.1); catalogued as COSV99896680; called by muse, mutect2, varscan2
- NEGR1 | c.80T>A p.L27Q | Missense Mutation (SNP) | VAF 12/78 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.601); catalogued as COSV100749933, COSV63271537; called by muse, mutect2, varscan2
- NKPD1 | c.2357C>G p.A786G | Missense Mutation (SNP) | VAF 18/38 reads (47%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.1); catalogued as COSV99675119; called by muse, mutect2, varscan2
- NLRP3 | c.1519C>G p.Q507E | Missense Mutation (SNP) | VAF 31/79 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.636); catalogued as COSV100276803; called by muse, mutect2, varscan2
- NTRK1 | c.1856C>A p.P619Q | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT tolerated (0.54); PolyPhen possibly damaging (0.487); catalogued as COSV100693876; called by muse, mutect2, varscan2
- NUDT1 | c.76G>A p.A26T (on ENST00000397048 / NM_198952.1; = p.A3T on NM_002452.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 12/112 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs139296148; called by muse, mutect2, varscan2
- NUP42 | c.1189G>T p.E397* | Nonsense Mutation (SNP) | VAF 51/144 reads (35%) | catalogued as COSV99331222; called by muse, mutect2, varscan2
- NXNL1 | c.269T>A p.F90Y | Missense Mutation (SNP) | VAF 24/91 reads (26%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.921); catalogued as COSV100112088; called by muse, mutect2, varscan2
- OPRL1 | c.1096G>T p.V366L | Missense Mutation (SNP) | VAF 22/55 reads (40%) | SIFT tolerated (0.48); PolyPhen benign (0.007); catalogued as COSV100402311; called by muse, mutect2, varscan2
- OR13C4 | c.464A>G p.N155S | Missense Mutation (SNP) | VAF 98/204 reads (48%) | SIFT tolerated (0.09); PolyPhen benign (0.442); catalogued as rs753871939, COSV99470343; called by muse, mutect2, varscan2
- OR2A2 | c.305T>C p.L102S | Missense Mutation (SNP) | VAF 88/195 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.103); catalogued as COSV101286683, COSV68872675; called by muse, mutect2, varscan2
- OR2J2 | c.187T>C p.F63L | Missense Mutation (SNP) | VAF 99/211 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.684); catalogued as COSV101013497; called by muse, mutect2, varscan2
- OR2M4 | c.805G>A p.D269N | Missense Mutation (SNP) | VAF 18/90 reads (20%) | SIFT tolerated (0.53); PolyPhen benign (0.003); catalogued as COSV100141593; called by muse, mutect2, varscan2
- OR2M7 | c.458C>G p.S153C | Missense Mutation (SNP) | VAF 59/297 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.104); catalogued as COSV100522750; called by muse, mutect2, varscan2
- OR2T1 | c.217A>G p.I73V | Missense Mutation (SNP) | VAF 33/161 reads (20%) | SIFT tolerated (0.27); PolyPhen benign (0.255); catalogued as COSV100822364; called by muse, mutect2, varscan2
- OR51M1 | c.844C>G p.P282A | Missense Mutation (SNP) | VAF 19/44 reads (43%) | SIFT tolerated (0.06); PolyPhen benign (0.358); catalogued as COSV100150428; called by muse, mutect2, varscan2
- OR52R1 | c.763T>C p.Y255H | Missense Mutation (SNP) | VAF 67/113 reads (59%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs560063488, COSV100617816; called by muse, mutect2, varscan2
- OR52R1 | c.370G>T p.D124Y | Missense Mutation (SNP) | VAF 48/78 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100617817, COSV61889664; called by muse, mutect2, varscan2
- OR5I1 | c.206C>A p.S69* | Nonsense Mutation (SNP) | VAF 23/60 reads (38%) | catalogued as COSV100041754; called by muse, mutect2, varscan2
- OR5M1 | c.68T>C p.L23P | Missense Mutation (SNP) | VAF 47/108 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV101591623; called by muse, mutect2, varscan2
- OR7G2 | c.984del p.I329Yfs*16 | Frame Shift Del (DEL) | VAF 23/70 reads (33%) | catalogued as COSV59689172; called by mutect2, pindel, varscan2
- OSBP2 | c.2487G>A p.M829I | Missense Mutation (SNP) | VAF 20/44 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100213930; called by muse, mutect2, varscan2
- OTUD7B | c.1412C>T p.S471L | Missense Mutation (SNP) | VAF 83/158 reads (53%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100967848; called by muse, mutect2, varscan2
- PARN | c.605T>G p.L202* | Nonsense Mutation (SNP) | VAF 3/9 reads (33%) | catalogued as COSV100421464; called by muse, mutect2
- PCDH15 | c.2978A>C p.N993T | Missense Mutation (SNP) | VAF 29/91 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100229086, COSV57377775; called by muse, mutect2, varscan2
- PCNX3 | c.5866C>A p.P1956T | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.01); catalogued as COSV100856723; called by muse, mutect2, varscan2
- PDE1C | c.851G>T p.R284L | Missense Mutation (SNP) | VAF 30/84 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV100374191, COSV58530800; called by muse, mutect2, varscan2
- PDE3A | c.1322G>T p.W441L | Missense Mutation (SNP) | VAF 20/126 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV100762951; called by muse, mutect2, varscan2
- PDE3A | c.1323G>T p.W441C | Missense Mutation (SNP) | VAF 20/124 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100762952; called by muse, mutect2, varscan2
- PDE3B | c.2215C>A p.R739S | Missense Mutation (SNP) | VAF 29/60 reads (48%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV56385524, COSV99963462; called by muse, mutect2, varscan2
- PDK4 | c.398C>A p.T133K | Missense Mutation (SNP) | VAF 34/116 reads (29%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.809); catalogued as COSV99139040; called by muse, mutect2, varscan2
- PDZRN3 | c.2612C>T p.A871V | Missense Mutation (SNP) | VAF 31/115 reads (27%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.994); catalogued as rs1472294841, COSV55212681; called by muse, mutect2, varscan2
- PGLYRP2 | c.976C>A p.L326M | Missense Mutation (SNP) | VAF 19/68 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as COSV99484362; called by muse, mutect2, varscan2
- PIK3R6 | c.1069G>A p.G357S | Missense Mutation (SNP) | VAF 39/47 reads (83%) | SIFT tolerated (0.91); PolyPhen benign (0.006); catalogued as rs779932561, COSV61002559; called by muse, mutect2, varscan2
- PKD1 | c.1203G>A p.A401= | Splice Region (SNP) | VAF 29/66 reads (44%) | catalogued as rs750388049, COSV99239281; called by muse, mutect2, varscan2
- PLEC | c.7359G>A p.M2453I (on ENST00000322810 / NM_201380.4; = p.M2343I on NM_000445.5) | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.005); catalogued as COSV100519891; called by muse, varscan2
- PLEKHA4 | c.2293G>A p.E765K | Missense Mutation (SNP) | VAF 19/102 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.006); catalogued as COSV54361809; called by muse, mutect2, varscan2
- POU2F1 | c.2161A>T p.N721Y (on ENST00000541643 / NM_001365848.1; = p.N744Y on NM_002697.4) | Missense Mutation (SNP) | VAF 250/467 reads (54%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.085); catalogued as COSV99612656; called by muse, mutect2, varscan2
- PPA2 | c.608A>G p.K203R (on ENST00000341695 / NM_176869.3; = p.K174R on NM_006903.4) | Missense Mutation (SNP) | VAF 22/119 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100050039, COSV58993167; called by muse, mutect2, varscan2
- PPP2R2A | c.596G>A p.R199Q | Missense Mutation (SNP) | VAF 28/68 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs759228133, COSV60095739; called by muse, mutect2, varscan2
- PPP4R4 | c.1861G>A p.V621M | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV100429119; called by muse, mutect2, varscan2
- PRKN | c.199G>T p.V67F | Missense Mutation (SNP) | VAF 26/91 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as rs1406898777, COSV100630137; called by muse, mutect2, varscan2
- PTPRB | c.550A>C p.T184P | Missense Mutation (SNP) | VAF 10/19 reads (53%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.811); catalogued as COSV99717183, COSV99719399; called by muse, mutect2, varscan2
- PTPRR | c.513C>G p.N171K | Missense Mutation (SNP) | VAF 23/91 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.045); catalogued as COSV99319076; called by muse, mutect2, varscan2
- QKI | c.196G>T p.E66* | Nonsense Mutation (SNP) | VAF 21/93 reads (23%) | catalogued as COSV99276762; called by muse, mutect2, varscan2
- RAMP3 | c.84C>G p.C28W | Missense Mutation (SNP) | VAF 29/97 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99642479; called by muse, mutect2, varscan2
- RBM24 | c.711G>T p.*237Yext*42 (on ENST00000379052 / NM_001143942.2; = p.*192Yext*42 on NM_153020.2) | Nonstop Mutation (SNP) | VAF 76/109 reads (70%) | catalogued as COSV100553203; called by muse, mutect2, varscan2
- RC3H2 | c.1865C>G p.P622R | Missense Mutation (SNP) | VAF 25/50 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.686); catalogued as COSV100606175; called by muse, mutect2, varscan2
- RFPL4B | c.481G>C p.G161R | Missense Mutation (SNP) | VAF 14/97 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV101480742, COSV71437891; called by muse, mutect2, varscan2
- RFX6 | c.1460C>A p.S487* | Nonsense Mutation (SNP) | VAF 18/94 reads (19%) | catalogued as COSV100264416, COSV60587009; called by muse, mutect2, varscan2
- RIN3 | c.89A>G p.D30G | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT tolerated (0.17); PolyPhen benign (0.001); catalogued as rs565297689, COSV99380186; called by muse, mutect2, varscan2
- RPA4 | c.22A>T p.S8C | Missense Mutation (SNP) | VAF 35/49 reads (71%) | SIFT deleterious (0); PolyPhen possibly damaging (0.615); catalogued as COSV100235960; called by muse, mutect2, varscan2
- RSPO2 | c.365G>A p.G122D | Missense Mutation (SNP) | VAF 28/65 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99410647; called by muse, mutect2, varscan2
- RUBCN | c.1756G>T p.A586S | Missense Mutation (SNP) | VAF 24/133 reads (18%) | SIFT tolerated (0.23); PolyPhen benign (0.07); catalogued as COSV99585304; called by muse, mutect2, varscan2
- RYR2 | c.1698A>C p.E566D | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.824); catalogued as rs1397154786, COSV100773273; called by muse, mutect2, varscan2
- SCN7A | c.5030C>A p.P1677H | Missense Mutation (SNP) | VAF 70/281 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.071); catalogued as COSV101313387; called by muse, mutect2, varscan2
- SCN7A | c.899G>C p.G300A | Missense Mutation (SNP) | VAF 14/28 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV101313388; called by muse, mutect2, varscan2
- SEMA4C | c.1034A>G p.Y345C | Missense Mutation (SNP) | VAF 90/254 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV100561222; called by muse, mutect2, varscan2
- SERPINF1 | c.775C>A p.L259I | Missense Mutation (SNP) | VAF 77/108 reads (71%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.923); catalogued as COSV99629030; called by muse, mutect2, varscan2
- SETBP1 | c.3838G>T p.V1280L | Missense Mutation (SNP) | VAF 26/64 reads (41%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs755003311, COSV56336748; called by muse, mutect2, varscan2
- SLC16A1 | c.1081G>T p.G361* | Nonsense Mutation (SNP) | VAF 14/40 reads (35%) | catalogued as COSV100856130; called by muse, mutect2, varscan2
- SLC28A3 | c.296C>T p.T99I | Missense Mutation (SNP) | VAF 67/163 reads (41%) | SIFT tolerated (0.17); PolyPhen benign (0.009); catalogued as COSV100883372; called by muse, mutect2, varscan2
- SLC39A14 | c.1171G>C p.A391P | Missense Mutation (SNP) | VAF 59/203 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99250075; called by muse, mutect2, varscan2
- SLC43A3 | c.1327A>G p.I443V | Missense Mutation (SNP) | VAF 169/274 reads (62%) | SIFT tolerated (0.11); PolyPhen benign (0.035); catalogued as rs1239296679, COSV100725282; called by muse, mutect2, varscan2
- SLC9A2 | c.1144A>T p.T382S | Missense Mutation (SNP) | VAF 36/91 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); catalogued as COSV99296965; called by muse, mutect2, varscan2
- SLC9B1 | c.1386G>T p.L462F | Missense Mutation (SNP) | VAF 25/360 reads (7%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.477); catalogued as COSV56468001, COSV99600341; called by muse, mutect2
- SMN1 | c.841A>T p.R281* | Nonsense Mutation (SNP) | VAF 24/66 reads (36%) | catalogued as COSV100665277; called by muse, mutect2, varscan2
- SMYD1 | c.1088A>T p.Y363F | Missense Mutation (SNP) | VAF 39/109 reads (36%) | SIFT tolerated (0.23); PolyPhen benign (0.001); catalogued as COSV101352547; called by muse, mutect2, varscan2
- SNAP91 | c.1549C>A p.P517T | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as COSV52119705, COSV99536945; called by muse, varscan2
- SOX11 | c.305C>T p.A102V | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58983439; called by muse, mutect2, varscan2
- SP4 | c.1393G>A p.G465R | Missense Mutation (SNP) | VAF 89/285 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99755173; called by muse, mutect2, varscan2
- SPATA16 | c.1691A>C p.Q564P | Missense Mutation (SNP) | VAF 82/281 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.994); catalogued as COSV100651790; called by muse, mutect2, varscan2
- SPATA31E1 | c.4328T>A p.L1443H | Missense Mutation (SNP) | VAF 38/80 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.937); catalogued as COSV100351225; called by muse, mutect2, varscan2
- SPIRE2 | c.1268C>A p.S423Y | Missense Mutation (SNP) | VAF 26/65 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0.018); catalogued as COSV100989057; called by muse, mutect2, varscan2
- SPTB | c.931G>T p.A311S | Missense Mutation (SNP) | VAF 28/122 reads (23%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.629); catalogued as COSV101072474; called by muse, mutect2, varscan2
- SPTBN1 | c.2138A>C p.E713A | Missense Mutation (SNP) | VAF 51/180 reads (28%) | SIFT tolerated (0.45); PolyPhen benign (0.014); catalogued as COSV100443596; called by muse, mutect2, varscan2
- ST6GALNAC3 | c.247G>T p.V83L | Missense Mutation (SNP) | VAF 20/89 reads (22%) | PolyPhen possibly damaging (0.901); catalogued as COSV100085782; called by muse, mutect2, varscan2
- SUGP2 | c.200G>C p.G67A | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT tolerated (0.13); PolyPhen benign (0.037); catalogued as COSV100432445; called by muse, mutect2, varscan2
- SYNE1 | c.16492G>T p.A5498S (on ENST00000367255 / NM_182961.4; = p.A5427S on NM_033071.3) | Missense Mutation (SNP) | VAF 20/99 reads (20%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as COSV54976801; called by muse, mutect2, varscan2
- TENM1 | c.1484G>A p.G495D | Missense Mutation (SNP) | VAF 89/120 reads (74%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as rs1393053432, COSV100951225; called by muse, mutect2, varscan2
- TGIF2LX | c.401A>C p.H134P | Missense Mutation (SNP) | VAF 78/109 reads (72%) | SIFT deleterious (0.05); PolyPhen benign (0.369); catalogued as COSV99383566; called by muse, mutect2, varscan2
- THAP12 | c.1762C>A p.Q588K | Missense Mutation (SNP) | VAF 16/83 reads (19%) | SIFT tolerated (0.2); PolyPhen benign (0.039); catalogued as COSV99473347; called by muse, mutect2, varscan2
- THBS1 | c.1836C>A p.D612E | Missense Mutation (SNP) | VAF 72/213 reads (34%) | SIFT tolerated (0.97); PolyPhen benign (0); catalogued as COSV99528541; called by muse, mutect2, varscan2
- TLE4 | c.1025G>T p.G342V | Missense Mutation (SNP) | VAF 49/171 reads (29%) | SIFT tolerated (0.1); PolyPhen benign (0.097); catalogued as rs778270483, COSV54635764; called by muse, mutect2, varscan2
- TLN2 | c.7462G>T p.V2488F | Missense Mutation (SNP) | VAF 69/192 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.853); catalogued as COSV100170325; called by muse, mutect2
- TLR9 | c.1916G>A p.R639H | Missense Mutation (SNP) | VAF 53/78 reads (68%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs771867596, COSV100645514; called by muse, mutect2, varscan2
- TMEM119 | c.343G>T p.A115S | Missense Mutation (SNP) | VAF 17/77 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV101219581; called by muse, mutect2, varscan2
- TMPO | c.687_688del p.E230Dfs*2 | Frame Shift Del (DEL) | VAF 12/50 reads (24%) | catalogued as rs770288022; called by mutect2, pindel, varscan2
- TNR | c.3759C>A p.Y1253* | Nonsense Mutation (SNP) | VAF 21/134 reads (16%) | catalogued as COSV99692100; called by muse, mutect2, varscan2
- TNRC6C | c.1640G>A p.S547N | Missense Mutation (SNP) | VAF 63/221 reads (29%) | SIFT tolerated (0.84); PolyPhen benign (0); catalogued as rs1395312868, COSV100050870; called by muse, mutect2, varscan2
- TOGARAM2 | c.1289G>T p.W430L | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as COSV101091563; called by muse, mutect2, varscan2
- TOPBP1 | c.1256C>A p.P419H | Missense Mutation (SNP) | VAF 16/74 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV99605987; called by muse, mutect2, varscan2
- TRIM55 | c.1219G>C p.D407H | Missense Mutation (SNP) | VAF 19/65 reads (29%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.259); catalogued as COSV52546275, COSV99397316; called by muse, mutect2, varscan2
- TRIM58 | c.1210C>A p.Q404K | Missense Mutation (SNP) | VAF 74/160 reads (46%) | SIFT tolerated (0.34); PolyPhen benign (0.062); catalogued as COSV100825367, COSV63569292; called by muse, mutect2, varscan2
- TRIM59 | c.1105C>G p.L369V | Missense Mutation (SNP) | VAF 10/77 reads (13%) | SIFT tolerated (0.43); PolyPhen benign (0.001); catalogued as COSV59087063; called by muse, mutect2, varscan2
- TRIM9 | c.524C>T p.P175L | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV100032392; called by muse, mutect2, varscan2
- TRIML1 | c.452A>T p.K151M | Missense Mutation (SNP) | VAF 36/77 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.62); catalogued as COSV100206407; called by muse, mutect2, varscan2
- TRPC3 | c.739G>A p.E247K (on ENST00000379645 / NM_001366479.2; = p.E174K on NM_003305.2) | Missense Mutation (SNP) | VAF 33/58 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs868163943, COSV53377777; called by muse, mutect2, varscan2
- TRRAP | c.11473C>T p.L3825F (on ENST00000359863 / NM_001244580.1; = p.L3796F on NM_003496.3) | Missense Mutation (SNP) | VAF 37/59 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV100705513; called by muse, mutect2, varscan2
- TSGA10 | c.465T>G p.D155E | Missense Mutation (SNP) | VAF 37/104 reads (36%) | SIFT tolerated (0.65); PolyPhen benign (0.103); catalogued as COSV100747856; called by muse, mutect2, varscan2
- TSTD2 | c.721G>T p.D241Y | Missense Mutation (SNP) | VAF 26/95 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100359230; called by muse, mutect2, varscan2
- TTN | c.73298G>T p.G24433V (on ENST00000591111; = p.G17009V on NM_003319.4) | Missense Mutation (SNP) | VAF 83/367 reads (23%) | PolyPhen probably damaging (1); catalogued as COSV100634628; called by muse, mutect2, varscan2
- TTN | c.66005T>A p.V22002D (on ENST00000591111; = p.V14578D on NM_003319.4) | Missense Mutation (SNP) | VAF 19/40 reads (48%) | PolyPhen possibly damaging (0.885); catalogued as COSV100634632; called by muse, mutect2, varscan2
- TTN | c.65692C>T p.L21898F (on ENST00000591111; = p.L14474F on NM_003319.4) | Missense Mutation (SNP) | VAF 344/664 reads (52%) | PolyPhen probably damaging (0.999); catalogued as rs979501326, COSV100634635; called by muse, mutect2, varscan2
- TTN | c.39754C>G p.L13252V (on ENST00000591111; = p.L5828V on NM_003319.4) | Missense Mutation (SNP) | VAF 18/141 reads (13%) | PolyPhen benign (0.058); catalogued as COSV100634637; called by muse, mutect2, varscan2
- TTN | c.12272C>A p.A4091D (on ENST00000591111; = p.A4045D on NM_003319.4) | Missense Mutation (SNP) | VAF 36/189 reads (19%) | catalogued as COSV100634645; called by muse, mutect2, varscan2
- TUBAL3 | c.928G>A p.V310I | Missense Mutation (SNP) | VAF 20/77 reads (26%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.013); catalogued as COSV100990600; called by muse, mutect2, varscan2
- TUBE1 | c.260G>T p.G87V | Missense Mutation (SNP) | VAF 25/126 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100898332; called by muse, mutect2, varscan2
- UBR1 | c.1270G>T p.V424F | Missense Mutation (SNP) | VAF 44/98 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99318052; called by muse, mutect2, varscan2
- UGT2B28 | c.26T>C p.L9P | Missense Mutation (SNP) | VAF 23/113 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as rs1488957145, COSV100159104; called by muse, mutect2, varscan2
- UGT3A1 | c.880G>C p.G294R | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs752552180, COSV99955465; called by muse, mutect2, varscan2
- UNC13A | c.4540C>G p.Q1514E | Missense Mutation (SNP) | VAF 100/235 reads (43%) | SIFT tolerated (0.6); PolyPhen benign (0.003); catalogued as COSV53194150, COSV99409864; called by muse, mutect2, varscan2
- USP13 | c.1819G>T p.D607Y | Missense Mutation (SNP) | VAF 50/249 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV99831876; called by muse, mutect2, varscan2
- USP26 | c.1710C>A p.F570L | Missense Mutation (SNP) | VAF 53/75 reads (71%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as COSV100896714, COSV100896797; called by muse, mutect2, varscan2
- VWCE | c.563C>G p.T188S | Missense Mutation (SNP) | VAF 99/465 reads (21%) | SIFT tolerated (0.23); PolyPhen benign (0.083); catalogued as rs763392587, COSV100076265; called by muse, mutect2, varscan2
- VWCE | c.406G>C p.V136L | Missense Mutation (SNP) | VAF 17/67 reads (25%) | SIFT tolerated (0.25); PolyPhen benign (0.033); catalogued as COSV100076266; called by muse, mutect2, varscan2
- WDR43 | c.1027G>A p.D343N | Missense Mutation (SNP) | VAF 20/67 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.389); catalogued as COSV99943185; called by muse, mutect2, varscan2
- WDR49 | c.1931A>G p.E644G (on ENST00000308378 / NM_001366158.1; = p.E985G on NM_001348951.2 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 88/367 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.081); catalogued as COSV100394035; called by muse, mutect2, varscan2
- XIRP2 | c.4165G>T p.V1389F (on ENST00000628543; = p.V1564F on NM_152381.6) | Missense Mutation (SNP) | VAF 21/98 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.809); catalogued as COSV99748750; called by muse, mutect2, varscan2
- XPNPEP1 | c.1493G>A p.S498N | Missense Mutation (SNP) | VAF 25/52 reads (48%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.88); catalogued as COSV100451168; called by muse, mutect2, varscan2
- YLPM1 | c.3352G>T p.G1118C | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.632); catalogued as COSV99461660; called by muse, mutect2, varscan2
- ZBTB37 | c.470C>A p.P157Q | Missense Mutation (SNP) | VAF 57/106 reads (54%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as COSV100774662; called by muse, mutect2, varscan2
- ZFYVE16 | c.1270G>A p.G424S | Missense Mutation (SNP) | VAF 32/47 reads (68%) | SIFT tolerated (0.39); PolyPhen benign (0.057); catalogued as COSV100566677; called by muse, mutect2, varscan2
- ZNF253 | c.805A>G p.T269A | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as COSV100849620; called by muse, mutect2, varscan2
- ZNF331 | c.1383C>A p.H461Q | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.2); catalogued as COSV99468164; called by muse, mutect2, varscan2
- ZNF358 | c.1441G>A p.G481S | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); catalogued as COSV99900980; called by muse, mutect2, varscan2
- ZNF57 | c.1596C>A p.H532Q | Missense Mutation (SNP) | VAF 26/99 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.009); catalogued as COSV100183082; called by muse, mutect2, varscan2
- ZNF595 | c.333A>T p.L111F | Missense Mutation (SNP) | VAF 28/60 reads (47%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.888); catalogued as COSV100227961; called by muse, mutect2, varscan2
- ZNF69 | c.198T>G p.S66R (on ENST00000429654 / NM_001364730.1; = p.S52R on NM_021915.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 43/89 reads (48%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs779030736, COSV60903955; called by muse, mutect2, varscan2
- ZNF92 | c.766C>A p.P256T (on ENST00000328747 / NM_152626.4; = p.P187T on NM_007139.4) | Missense Mutation (SNP) | VAF 6/84 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.791); catalogued as COSV100166026, COSV60876693; called by muse, mutect2
- ZSCAN1 | c.494C>A p.A165E | Missense Mutation (SNP) | VAF 24/112 reads (21%) | SIFT tolerated (0.14); PolyPhen benign (0.433); catalogued as COSV99992199; called by muse, mutect2, varscan2
- CSMD1 | c.10476del p.I3493Ffs*8 (on ENST00000520002; = p.I3492Ffs*8 on NM_033225.6) | Frame Shift Del (DEL) | VAF 6/25 reads (24%) | called by mutect2, pindel
- CYP19A1 | c.1385_1386del p.T462Ifs*7 | Frame Shift Del (DEL) | VAF 37/112 reads (33%) | called by mutect2, pindel, varscan2
- DEPDC1 | c.1500del p.K501Nfs*15 | Frame Shift Del (DEL) | VAF 24/65 reads (37%) | called by mutect2, pindel, varscan2
- GDF10 | c.472T>A p.S158T | Missense Mutation (SNP) | VAF 26/37 reads (70%) | SIFT tolerated (0.05); PolyPhen benign (0.076); called by muse, mutect2, varscan2
- IGHV4-28 | c.121T>A p.C41S | Missense Mutation (SNP) | VAF 52/196 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- IGKV1-9 | c.256G>T p.G86C | Missense Mutation (SNP) | VAF 122/306 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LACTB | c.502del p.S168Vfs*46 | Frame Shift Del (DEL) | VAF 26/65 reads (40%) | called by mutect2, pindel, varscan2
- MYLIP | c.138dup p.T47Yfs*3 | Frame Shift Ins (INS) | VAF 61/125 reads (49%) | called by mutect2, pindel, varscan2
- RHOBTB2 | c.1921_1923del p.N641del | In Frame Del (DEL) | VAF 12/42 reads (29%) | called by pindel, varscan2
- SLCO1B1 | c.1411del p.E471Nfs*9 | Frame Shift Del (DEL) | VAF 19/97 reads (20%) | called by mutect2, pindel, varscan2
- TTC14 | c.1062del p.G355Efs*3 | Frame Shift Del (DEL) | VAF 50/212 reads (24%) | called by mutect2, pindel, varscan2
- ZNF804B | c.3763dup p.I1255Nfs*76 | Frame Shift Ins (INS) | VAF 155/337 reads (46%) | called by mutect2, pindel, varscan2
- ABTB1 | c.1272G>A p.E424= (on ENST00000232744 / NM_172027.3; = p.E282= on NM_032548.3) | Silent (SNP) | VAF 9/42 reads (21%) | catalogued as rs768942536, COSV99230228; called by muse, mutect2, varscan2
- AHCYL2 | c.1332C>T p.V444= | Silent (SNP) | VAF 20/108 reads (19%) | catalogued as COSV100273814; called by muse, mutect2, varscan2
- ARAP2 | c.4902C>T p.N1634= | Silent (SNP) | VAF 44/110 reads (40%) | catalogued as rs145645191, COSV58293530; called by muse, mutect2, varscan2
- ART4 | c.51A>G p.V17= | Silent (SNP) | VAF 12/60 reads (20%) | catalogued as COSV99967021; called by muse, mutect2, varscan2
- BPIFB6 | c.483G>C p.L161= | Silent (SNP) | VAF 39/85 reads (46%) | catalogued as COSV100848562; called by muse, mutect2, varscan2
- CALCR | c.798G>T p.V266= (on ENST00000649521 / NM_001164737.2; = p.V250= on NM_001742.4) | Silent (SNP) | VAF 65/145 reads (45%) | catalogued as rs1456234776, COSV100810914; called by muse, mutect2, varscan2
- CC2D1A | c.216C>T p.A72= | Silent (SNP) | VAF 9/20 reads (45%) | catalogued as COSV100528766; called by muse, mutect2, varscan2
- CCDC173 | c.1395T>C p.A465= | Silent (SNP) | VAF 104/503 reads (21%) | catalogued as COSV53646827, COSV99645078; called by muse, varscan2
- CEBPA | c.825G>A p.K275= | Silent (SNP) | VAF 9/30 reads (30%) | catalogued as COSV100204765, COSV57196402; called by muse, mutect2
- CFAP77 | c.904C>A p.R302= | Silent (SNP) | VAF 55/133 reads (41%) | catalogued as COSV100546200; called by muse, mutect2, varscan2
- CHRD | c.2220G>C p.P740= | Silent (SNP) | VAF 20/132 reads (15%) | catalogued as COSV99200225, COSV99200969; called by muse, mutect2, varscan2
- COL4A5 | c.3798A>G p.P1266= | Silent (SNP) | VAF 71/100 reads (71%) | catalogued as COSV100090479; called by muse, mutect2, varscan2
- COL5A1 | c.3723G>A p.E1241= | Silent (SNP) | VAF 25/100 reads (25%) | catalogued as COSV100880702; called by muse, mutect2, varscan2
- CRACD | c.495A>T p.P165= | Silent (SNP) | VAF 41/111 reads (37%) | catalogued as COSV99950174; called by muse, mutect2, varscan2
- DHRS2 | c.573G>T p.A191= | Silent (SNP) | VAF 55/124 reads (44%) | catalogued as COSV99160857; called by muse, mutect2, varscan2
- DLEC1 | c.594C>T p.S198= | Silent (SNP) | VAF 40/143 reads (28%) | catalogued as rs749238302, COSV100343736; called by muse, mutect2, varscan2
- DMD | c.7723T>C p.L2575= | Silent (SNP) | VAF 40/58 reads (69%) | catalogued as COSV100629819; called by muse, mutect2, varscan2
- DNAH3 | c.3468C>T p.I1156= | Silent (SNP) | VAF 45/98 reads (46%) | catalogued as COSV99771269; called by muse, mutect2, varscan2
- DTX4 | c.549G>T p.S183= | Silent (SNP) | VAF 36/93 reads (39%) | catalogued as COSV99916048; called by muse, mutect2, varscan2
- EEF2KMT | c.337T>C p.L113= | Silent (SNP) | VAF 14/85 reads (16%) | catalogued as rs1456178245, COSV101435315; called by muse, mutect2, varscan2
- EGR4 | c.423C>G p.P141= (on ENST00000545030; = p.P38= on NM_001965.4) | Silent (SNP) | VAF 8/21 reads (38%) | catalogued as COSV101474282; called by muse, mutect2, varscan2
- ENPP1 | c.894T>A p.P298= | Silent (SNP) | VAF 6/24 reads (25%) | catalogued as COSV100719678; called by muse, mutect2, varscan2
- EXD3 | c.1947T>A p.G649= | Silent (SNP) | VAF 34/64 reads (53%) | catalogued as COSV100574059; called by muse, mutect2, varscan2
- F5 | c.3453A>G p.P1151= | Silent (SNP) | VAF 74/330 reads (22%) | catalogued as rs1242801911, COSV100889289; called by muse, mutect2, varscan2
- FAT4 | c.14163G>A p.R4721= | Silent (SNP) | VAF 56/98 reads (57%) | catalogued as COSV100630541; called by muse, mutect2, varscan2
- GAREM1 | c.1230G>T p.G410= | Silent (SNP) | VAF 39/98 reads (40%) | catalogued as COSV52505384; called by muse, mutect2, varscan2
- GBF1 | c.5112A>G p.E1704= (on ENST00000369983 / NM_001377137.1; = p.E1703= on NM_004193.3) | Silent (SNP) | VAF 309/517 reads (60%) | catalogued as COSV100890718; called by muse, mutect2, varscan2
- GSTK1 | c.240C>T p.P80= | Silent (SNP) | VAF 131/342 reads (38%) | catalogued as COSV100621846; called by muse, mutect2, varscan2
- IGHV4-34 | c.129C>T p.T43= | Silent (SNP) | VAF 28/93 reads (30%) | catalogued as rs747045703; called by muse, mutect2, varscan2
- INCENP | c.2493C>T p.S831= (on ENST00000394818 / NM_001040694.2; = p.S827= on NM_020238.3) | Silent (SNP) | VAF 55/116 reads (47%) | catalogued as COSV99611773; called by muse, mutect2, varscan2
- KRTAP19-5 | c.105G>A p.L35= | Silent (SNP) | VAF 77/193 reads (40%) | catalogued as COSV100478626; called by muse, mutect2, varscan2
- MED30 | c.384G>T p.R128= | Silent (SNP) | VAF 12/27 reads (44%) | catalogued as COSV99816194; called by muse, mutect2, varscan2
- MEF2A | c.1059G>A p.S353= (on ENST00000557942 / NM_001319206.2; = p.S347= on NM_005587.4 and 8 other RefSeq transcripts) | Silent (SNP) | VAF 18/68 reads (26%) | catalogued as rs572494865, COSV100574035; called by muse, mutect2, varscan2
- MGA | c.7467T>C p.T2489= (on ENST00000219905 / NM_001164273.1; = p.T2280= on NM_001080541.2) | Silent (SNP) | VAF 6/21 reads (29%) | catalogued as COSV99581980; called by muse, mutect2, varscan2
- MPO | c.762A>G p.Q254= | Silent (SNP) | VAF 17/51 reads (33%) | catalogued as COSV99833120; called by muse, mutect2, varscan2
- MTMR6 | c.1272G>A p.Q424= | Silent (SNP) | VAF 9/38 reads (24%) | catalogued as COSV101110870; called by muse, mutect2, varscan2
- MYH8 | c.5376G>T p.T1792= | Silent (SNP) | VAF 145/207 reads (70%) | catalogued as rs200951146, COSV101238973, COSV67968950; called by muse, mutect2, varscan2
- NAALADL1 | c.609G>C p.V203= | Silent (SNP) | VAF 13/66 reads (20%) | catalogued as COSV100368303; called by muse, mutect2, varscan2
- NALCN | c.4974C>A p.A1658= | Silent (SNP) | VAF 24/49 reads (49%) | catalogued as COSV99218424; called by muse, mutect2, varscan2
- NPBWR1 | c.900C>T p.S300= | Silent (SNP) | VAF 21/78 reads (27%) | catalogued as rs1332989631, COSV100488342; called by muse, mutect2, varscan2
- ONECUT2 | c.462C>A p.L154= | Silent (SNP) | VAF 8/40 reads (20%) | catalogued as COSV101529826; called by muse, mutect2, varscan2
- OR10A5 | c.621G>A p.V207= | Silent (SNP) | VAF 91/152 reads (60%) | catalogued as COSV100203524; called by muse, mutect2, varscan2
- OR2W3 | c.852C>T p.L284= | Silent (SNP) | VAF 7/51 reads (14%) | catalogued as COSV100831887; called by muse, mutect2, varscan2
- OR6F1 | c.702G>T p.R234= | Silent (SNP) | VAF 66/145 reads (46%) | catalogued as COSV57466841; called by muse, mutect2, varscan2
- OR6T1 | c.495C>T p.S165= | Silent (SNP) | VAF 32/76 reads (42%) | catalogued as rs757490052, COSV100190239; called by muse, mutect2, varscan2
- PCDHA2 | c.1303C>T p.L435= | Silent (SNP) | VAF 82/140 reads (59%) | catalogued as rs1554119803, COSV100974187; called by muse, mutect2, varscan2
- PCDHB11 | c.642T>C p.A214= | Silent (SNP) | VAF 52/80 reads (65%) | catalogued as COSV99505182; called by muse, mutect2, varscan2
- PIK3AP1 | c.1449T>C p.S483= | Silent (SNP) | VAF 123/187 reads (66%) | catalogued as COSV100226325; called by muse, mutect2, varscan2
- PPFIA2 | c.435G>T p.V145= | Silent (SNP) | VAF 6/29 reads (21%) | catalogued as COSV100335593; called by muse, mutect2, varscan2
- PPP4R3B | c.1170A>T p.L390= | Silent (SNP) | VAF 27/89 reads (30%) | catalogued as COSV99702849; called by muse, mutect2, varscan2
- PRUNE2 | c.7881T>A p.P2627= | Silent (SNP) | VAF 22/52 reads (42%) | catalogued as COSV100945282; called by muse, mutect2, varscan2
- PTPN13 | c.2283G>A p.E761= | Silent (SNP) | VAF 5/25 reads (20%) | catalogued as COSV100365587; called by mutect2, varscan2
- RAPGEF2 | c.2484A>G p.K828= | Silent (SNP) | VAF 19/34 reads (56%) | catalogued as COSV100031792; called by muse, mutect2, varscan2
- RHOXF2B | c.219C>A p.G73= | Silent (SNP) | VAF 69/122 reads (57%) | catalogued as rs782311543, COSV101003941; called by muse, mutect2, varscan2
- RPS4X | c.588C>A p.T196= | Silent (SNP) | VAF 27/38 reads (71%) | catalogued as COSV100289188; called by muse, mutect2, varscan2
- SCN9A | c.2352T>C p.T784= (on ENST00000303354; = p.T773= on NM_002977.3) | Silent (SNP) | VAF 22/37 reads (59%) | catalogued as COSV100314561; called by muse, mutect2, varscan2
- SLIT1 | c.375G>T p.P125= | Silent (SNP) | VAF 149/283 reads (53%) | catalogued as COSV99822785; called by muse, mutect2, varscan2
- SPEG | c.2154C>G p.P718= | Silent (SNP) | VAF 140/209 reads (67%) | catalogued as COSV100405885, COSV56669165; called by muse, mutect2, varscan2
- SPNS3 | c.546C>T p.P182= | Silent (SNP) | VAF 41/74 reads (55%) | catalogued as rs756864042, COSV61071683; called by muse, mutect2, varscan2
- SYT7 | c.972G>T p.T324= | Silent (SNP) | VAF 48/128 reads (38%) | catalogued as COSV55654900, COSV99802291; called by muse, mutect2, varscan2
- TEP1 | c.5703G>T p.T1901= | Silent (SNP) | VAF 36/175 reads (21%) | catalogued as COSV99403522; called by muse, mutect2, varscan2
- THOC1 | c.1230G>C p.T410= | Silent (SNP) | VAF 15/31 reads (48%) | catalogued as rs747161472, COSV99863655; called by muse, varscan2
- TLN2 | c.3324G>C p.L1108= | Silent (SNP) | VAF 6/65 reads (9%) | catalogued as rs1163423746, COSV100170324; called by muse, mutect2, varscan2
- TMC2 | c.2217C>T p.T739= | Silent (SNP) | VAF 45/173 reads (26%) | catalogued as COSV100728053; called by muse, mutect2, varscan2
- TMED1 | c.15C>G p.G5= | Silent (SNP) | VAF 7/14 reads (50%) | catalogued as COSV99284302; called by muse, mutect2, varscan2
- TNN | c.480C>A p.G160= | Silent (SNP) | VAF 3/37 reads (8%) | called by muse, mutect2
- TRBV28 | c.343T>C p.*115= | Silent (SNP) | VAF 17/40 reads (43%) | called by muse, mutect2, varscan2
- TRIM58 | c.1209C>A p.L403= | Silent (SNP) | VAF 73/159 reads (46%) | catalogued as COSV100825366; called by muse, mutect2, varscan2
- TSPYL6 | c.1131A>T p.P377= | Silent (SNP) | VAF 50/148 reads (34%) | catalogued as COSV100336954; called by muse, mutect2, varscan2
- TTN | c.100564C>T p.L33522= (on ENST00000591111; = p.L26098= on NM_003319.4) | Silent (SNP) | VAF 72/549 reads (13%) | catalogued as COSV100634623; called by muse, mutect2, varscan2
- ULK2 | c.1857G>A p.L619= | Silent (SNP) | VAF 10/40 reads (25%) | catalogued as COSV100861042; called by muse, mutect2, varscan2
- USH2A | c.10728C>A p.A3576= | Silent (SNP) | VAF 37/97 reads (38%) | catalogued as COSV104408065, COSV56411937; called by muse, mutect2, varscan2
- WDR72 | c.927G>C p.L309= | Silent (SNP) | VAF 21/63 reads (33%) | catalogued as COSV100855225; called by muse, mutect2, varscan2
- WRAP53 | c.1080C>T p.L360= | Silent (SNP) | VAF 17/44 reads (39%) | catalogued as rs775212492, COSV99873040; called by muse, mutect2, varscan2
- YES1 | c.1344G>C p.R448= | Silent (SNP) | VAF 35/176 reads (20%) | catalogued as COSV100099566, COSV100100027; called by muse, mutect2, varscan2
- ZWINT | c.738C>T p.P246= | Silent (SNP) | VAF 41/135 reads (30%) | catalogued as COSV100571590; called by muse, mutect2, varscan2
- ACOX1 | c.431-2735C>T | Intron (SNP) | VAF 13/71 reads (18%) | catalogued as COSV99504085; called by muse, mutect2, varscan2
- AL353804.4 | chrX:73825258 G>A | 5'Flank (SNP) | VAF 21/40 reads (53%) | called by muse, mutect2, varscan2
- DIO3 | chr14:101560325 C>A | 5'Flank (SNP) | VAF 6/43 reads (14%) | catalogued as rs1213025307; called by muse, mutect2, varscan2
- MYBPC1 | c.104-1651G>C | Intron (SNP) | VAF 26/76 reads (34%) | catalogued as COSV100638331; called by muse, mutect2, varscan2
- MYL3 | chr3:46831904 T>C | 3'Flank (SNP) | VAF 59/91 reads (65%) | catalogued as COSV101451283; called by muse, mutect2, varscan2
- OBSCN | c.18662-2781C>A | Intron (SNP) | VAF 6/30 reads (20%) | catalogued as COSV99485727; called by muse, mutect2, varscan2
- PPP1R9A | c.2758-2050G>A | Intron (SNP) | VAF 53/105 reads (50%) | catalogued as rs755003454, COSV56900110; called by muse, mutect2, varscan2
- SLC22A20P | n.1440C>T | RNA (SNP) | VAF 30/149 reads (20%) | catalogued as rs766043393; called by muse, mutect2, varscan2
- SSPOP | n.11244A>T | RNA (SNP) | VAF 5/12 reads (42%) | catalogued as COSV100948239; called by muse, mutect2
- SSPOP | n.12248G>A | RNA (SNP) | VAF 9/42 reads (21%) | catalogued as rs1193411045, COSV100948240; called by muse, mutect2, varscan2
- TTN | c.10360+1536G>C | Intron (SNP) | VAF 150/258 reads (58%) | catalogued as COSV100634646; called by muse, mutect2, varscan2
- XIRP2 | c.*503C>G | 3'UTR (SNP) | VAF 74/167 reads (44%) | catalogued as COSV99748754; called by muse, mutect2, varscan2
